Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M7-01A (Primary Tumor).

1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3.
Site: Endometrium C54.1 for 5/3/11

FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. NEGATIVE FOR TUMOR.
- B. OVARY WITH FOCAL SURFACE ADHESIONS.
- C. ECTATIC SEGMENT OF FALLOPIAN TUBE WITH CHRONIC INFLAMMATION.

PART 2: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY -

- A. NEGATIVE FOR TUMOR.
- B. OVARY WITH FOCAL SURFACE ADHESIONS.
- C. ECTATIC SEGMENT OF FALLOPIAN TUBE WITH CHRONIC INFLAMMATION.

PART 3: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY -

- A. INVASIVE MODERATELY DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA, ARISING IN A BACKGROUND OF COMPLEX ATYPICAL HYPERPLASIA.
- B. TUMOR INVOLVES ENTIRE ENDOMETRIAL CAVITY, LOWER UTERINE SEGMENT AND CERVIX AND INVADES TO A DEPTH OF 1.2 CM OF 1.6 CM THICK MYOMETRIUM AND INTO THE OUTER HALF OF CERVICAL STROMA.
- C. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- D. PATHOLOGIC STAGE: (see comment).
- E. PELVIC WASH - NEGATIVE.

PART 4: PELVIC LYMPH NODES, RIGHT, DISSECTION -

FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).

PART 5: RIGHT COMMON AND PERIAORTIC LYMPH NODES, DISSECTION -

FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

PART 6: PELVIC LYMPH NODES, LEFT, DISSECTION -

- A. METASTATIC CARCINOMA INVOLVES ONE OF SIX LYMPH NODES (1/6).
- B. EXTRACAPSULAR EXTENSION IS NOT IDENTIFIED.

PART 7: COMMON AND PERIAORTIC LYMPH NODES, LEFT, DISSECTION -

TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).

COMMENT:

The tumor is positive for ER and PR.

Although definitive lymphovascular space invasion is not identified, metastatic carcinoma is seen in one lymph node.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE: Moderately differentiated

NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 4.6 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION**: Greater than 1/2 thickness of myometrium

STRUCTURES INVOLVED:

Endocervical glands, Cervical stroma

ANGIOLYMPHATIC INVASION:

No

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 1

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 17

EXTRANODAL EXTENSION:

No

T STAGE, PATHOLOGIC:

pT2b

N STAGE, PATHOLOGIC:

pN1

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIIC

5/3/11

Source: NCI Genomic Data Commons file 2e898fe2-271d-4aef-a6e7-38a8dc8360d2 (TCGA-BG-A0M7.F9128DAE-F3D0-4738-AC20-E665F22DDC63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).